Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A3DR, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A3DR-01A (Primary Tumor).

Discrepancy	Yes	No
	10/21/11	

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

2) TOTAL THYROID WITH LIMITED NECK DISSECTION (THYROIDECTOMY):

SPECIMEN TYPE: Total thyroidectomy

TUMOR SITE: Left lobe

HISTOLOGIC TYPE: Papillary carcinoma

TUMOR SIZE (LARGEST NODULE):

Greatest dimension: 1.2 cm

FOCALITY: Unifocal

LYMPH NODES (ALL PARTS):

Metastatic carcinoma in 5 of 6 lymph nodes.

EXTENT OF INVASION (STAGING) PRIMARY TUMOR:

pT1: Tumor size less than or equal to 2.0 cm, limited to thyroid

REGIONAL LYMPH NODES:

pN1a: Nodal metastasis to Level VI (pretracheal, paratracheal, and prelaryngeal/Delphian) nodes

DISTANT METASTASIS:

pMx: Cannot be assessed

MARGINS: Margins are uninvolved

VENOUS/LYMPHATIC INVASION:

Indeterminate

ADDITIONAL PATHOLOGIC FINDINGS:

Parathyroid tissue, right

ICD-O-3

carcinoma, papillary, thyroid
8260/3

Site: thyroid, NOS C73.9

fw
10/21/11

Source: NCI Genomic Data Commons file 53a72b1a-6812-4c48-86bc-2cb9b88a33e2 (TCGA-ET-A3DR.7EABB2C4-F2D3-467D-B725-4D9F61B6F6FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).